CCDI case PBCKZM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/88743868-8bc6-4d41-977e-fbdc3d3b1165

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Teratoma, NOS: ICD-O-3 morphology code: 9080/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (71 days).

Biospecimens (3 samples)
- Sample 0DUCRJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUCRP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUCTX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
